Gene-level copy-number profile of tumor specimen C3L-06459-01 from CPTAC case C3L-06459, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 73.0 years (26,661 days).
Specimen C3L-06459-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45cb62ec-0e51-42ee-b928-eaf08c592faa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06459-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/d62127ce-7598-4c63-a63d-8b67e7f915b0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 673; copy number 2: 13,755; copy number 3: 26,983; copy number 4: 10,806; copy number 5: 3,265; copy number 6: 882; copy number 7: 1,125; copy number 8: 324; copy number 9: 128; copy number 10: 167; copy number 11: 18; copy number 12: 19; copy number 13: 46; copy number 14: 23; copy number 17: 5; copy number 19: 56; copy number 20: 9; copy number 21: 41; copy number 22: 6; copy number 23: 23; copy number 28: 14.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:85,557,978–85,735,921, 7 genes (within-gene range 0–2): AL589666.1, SYNCRIP, SNHG5, PKMP3, SNORD50B, AL355615.1, SMIM11P1.
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–2): DEFB108A.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr11:27,514,970–27,722,058, 4 genes (within-gene range 0–2): MIR8087, RNA5SP339, LINC00678, BDNF.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,004 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–71,585, 2 genes, copy number 7: OR4G11P, OR4F5.
- chr1:257,864–522,928, 10 genes, copy number 8 (within-gene range 3–8): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr3:196,763–409,417, 1 gene, copy number 12 (within-gene range 2–12): CHL1.
- chr3:308,714–14,489,349, 209 genes, copy number 9–28 (within-gene range 5–28) (broad region; genes not listed).
- chr3:14,572,852–18,444,817, 66 genes, copy number 8–23 (within-gene range 3–23) (broad region; genes not listed).
- chr6:60,281,444–60,546,660, 1 gene, copy number 7: AC244258.1.
- chr8:63,384,839–63,609,600, 5 genes, copy number 7: AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135.
- chr8:66,562,175–67,746,378, 23 genes, copy number 7 (within-gene range 6–7): MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10.
- chr8:124,811,042–127,742,951, 46 genes, copy number 7–8: AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr9:134,293,931–134,440,585, 4 genes, copy number 7: LINC02247, AL354796.1, RXRA, MIR4669.
- chr11:31,812,307–38,014,141, 107 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr12:65,017,468–71,800,286, 136 genes, copy number 10 (within-gene range 1–10) (broad region; genes not listed).
- chr13:107,868,823–111,901,264, 59 genes, copy number 7–9: AL359436.1, AL136964.1, LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, HCFC2P1, MYO16, MYO16-AS2, MYO16-AS1, AL161431.1, LINC00370, LINC01067, LINC00399, AL163541.1, LINC00676, IRS2, AL162497.1, AL355810.1, RN7SKP10, AL355974.1, AL390755.1, AL355974.2, LINC00396, RN7SL783P, AL390755.2, COL4A1, AL161773.1, COL4A2, MIR8073, COL4A2-AS2, COL4A2-AS1, RAB20, AL139385.1, NAXD, CARS2, ING1, RPL21P107, LINC00567, PRECSIT, ANKRD10, ANKRD10-IT1, AL442128.2, PARP1P1, AL442128.1, LINC00431, LINC00368, AL353704.2, ARHGEF7-AS2, ARHGEF7, ARHGEF7-IT1, ARHGEF7-AS1, AL353704.1, AL390754.1, TEX29, AL359649.1, LINC02337, LINC00354.
- chr14:18,333,726–18,412,264, 3 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2.
- chr14:23,058,564–23,560,778, 29 genes, copy number 7 (within-gene range 6–7): ACIN1, C14orf119, LMLN2, CEBPE, SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2.
- chr14:25,124,467–25,432,234, 4 genes, copy number 8: LINC02286, HMGN2P6, OR7K1P, AL079352.1.
- chr19:28,065,267–30,713,538, 46 genes, copy number 9–28 (within-gene range 2–28): AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1.
- chr20:87,250–13,996,443, 277 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr20:22,885,670–64,327,972, 974 genes, copy number 7–9 (broad region; genes not listed).
- chr21:10,640,028–10,649,835, 2 genes, copy number 7: AF254982.1, IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 299. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
